TARGET case TARGET-10-PATELK — Acute Lymphoblastic Leukemia - Phase II (TARGET-ALL-P2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/13b25ed5-cf0d-4a0f-bb1b-a3e200cdaebb

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Age at index: 2 years; Vital status: Dead; Days to death: 676 days (1.9 years).

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 2.3 years (851 days); Year of diagnosis: 2010; Days to last follow up: 676 days (1.9 years).
   Treatment given: Protocol identifier: AALL0232.

Follow-up (3 entries)
- Days to follow up: 512 days (1.4 years); Days to first event: 512 days (1.4 years); First event: Relapse.
- Days to follow up: 676 days (1.9 years); Progression or recurrence: Yes; Progression or recurrence anatomic site: Nervous system, NOS; Year of follow up: 2011.
- Days to follow up: 676 days (1.9 years); Progression or recurrence: Yes; Progression or recurrence anatomic site: Bone marrow.

Molecular and laboratory tests (laboratory values grouped by visit day)
- BCR–ABL1 fusion: Negative.
- ETV6–RUNX1 fusion (FISH): Negative.
- KMT2A rearrangement (FISH): Negative.
- Trisomy 10: Negative.
- Trisomy 4: Negative.
- Day 0: Leukocytes 391 ×10³/µL.
- Day 8: Bone Marrow blast count 60%; Minimal Residual Disease (Flow Cytometry) 1.8%.
- Day 15: Bone Marrow blast count 2%.
- Day 29: Bone Marrow blast count 4%; Minimal Residual Disease (Flow Cytometry) 0%.

Biospecimens (3 samples)
- Samples TARGET-10-PATELK-03A, TARGET-10-PATELK-03B (2 with the same recorded description): Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
- Sample TARGET-10-PATELK-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Dicentric_20230727.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 676
- WBC at Diagnosis: 391
- CNS Status at Diagnosis: CNS 1
- MRD Day 8: 1.8
- MRD Day 8 Sensitivity: 0.01
- MRD Day 29: 0
- MRD Day 29 Sensitivity: 0.01
- Bone Marrow Site of Relapse: Yes
- CNS Site of Relapse: Yes
- Testes Site of Relapse: No
- Other Site of Relapse: No
- ETV6 RUNX1 Fusion Status: Negative
- TRISOMY 4 10 Status: Negative
- MLL Status: Negative
- BCR ABL1 Status: Negative
- BMA Blasts Day 8: 60
- BMA Blasts Day 15: 2
- BMA Blasts Day 29: 4
- Karyotype: 46,XX,dic(7;9)(q10;q10),add(12)(p13),+mar[12]
- DNA Index: 1
- Cell of Origin: B-Precursor
